Somatic mutation profile of tumor specimen 0E0CT7 from CCDI case PBCVDN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E0CT7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6ebdb16-e798-4e0e-8632-69498b80289c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0JS3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b47aaba-f3ef-42f5-9d35-0f72415b98d7

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MED23 | c.2936C>T p.P979L | Missense Mutation (SNP) | VAF 23/468 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs1419291635; called by muse, mutect2
- NPR1 | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 17/277 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64140237; called by muse, mutect2
- RCBTB2 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 48/878 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs773567696; called by muse, mutect2
- ADGRG6 | c.2350G>T p.D784Y | Missense Mutation (SNP) | VAF 34/594 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2
- CEP85L | c.2127G>T p.L709F | Missense Mutation (SNP) | VAF 36/668 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.027); called by muse, mutect2
- ENAM | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 40/272 reads (15%) | called by muse, mutect2, varscan2
- ZFHX4 | c.6860A>G p.N2287S | Missense Mutation (SNP) | VAF 43/653 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- C20orf194 | c.1371C>G p.V457= | Silent (SNP) | VAF 16/230 reads (7%) | called by muse, mutect2
- GMPR2 | c.834T>C p.Y278= (on ENST00000355299 / NM_001351022.2; = p.Y296= on NM_016576.5) | Silent (SNP) | VAF 22/187 reads (12%) | catalogued as rs374877136; called by muse, mutect2, varscan2
